Surgical pathology report (de-identified scan), TCGA case TCGA-E1-A7YK, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Duke, specimen TCGA-E1-A7YK-01A (Primary Tumor).

[page 1 of 4]
Patient: [REDACTED]

Surgical Pathology: Additional Info [REDACTED] Acc# [REDACTED]

Surg Path

CLINICAL HISTORY:

Per [REDACTED] : [REDACTED]-year-old male developed confusion on [REDACTED] at home and had a seizure [REDACTED]. Brain biopsy on [REDACTED] showed an astrocytoma.

The MRI of the brain [REDACTED] shows a region of abnormal parenchymal signal with discontinuous, nodular enhancement seen in the inferolateral aspect of the left temporal lobe.

GROSS EXAMINATION:

A. "Brain tissue (AF1)", received fresh for frozen section placed in formalin at [REDACTED] 3.3 x 2.2 x 1 cm fragment of white-pink soft tissue is received. A representative section is frozen as AF1, frozen remnant submitted in A1. Additional representative tissue submitted in A2, with a section retained in formalin.

INTRA OPERATIVE CONSULTATION:

A. "Brain tissue":AF1 (representative)- glioma with gemistocytes

MICROSCOPIC EXAMINATION:

Microscopic examination shows brain infiltrated by a glial neoplasm characterized by cellular pleomorphism, including prominent gemistocytes, and perivascular lymphocytic inflammation. Scattered mitotic figures are seen. No microvascular changes or necrosis are seen.

GFAP: highlights tumor cells

HAM56: does not demonstrate a macrophage infiltrate

Ki-67 labeling index: 3%

IMMUNOHISTOCHEMICAL FINDINGS:

The immunoperoxidase tests reported herein were developed and their performance characteristics were determined by the [REDACTED]

Some of them may not be cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvements Amendments of 1988 (CLIA) as qualified to perform high complexity clinical testing.

DIAGNOSIS:

A. "BRAIN TISSUE" (CRANIOTOMY):

ANAPLASTIC GEMISTOCYTIC ASTROCYTOMA (WHO GRADE III).

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

Electronically signed: [REDACTED]

ADDENDUM 1:

Please see Image Cytometry Report tests.

for results of supplementary

Handwritten notes:
NGS 760-0-3
Astrocytoma grade III 945/13
Astrocytoma - gemistocytic 9411/13
Site: Brain, representative NGS 671.0
NGS 515/14

[page 2 of 4]
FISH INTERPRETATION SUMMARY:

CHROMOSOME 7 CENTROMERE - POLYSOMY (32% OF TUMOR CELLS EXHIBIT POLYSOMY)

EGFR - POLYSOMY (35% OF TUMOR CELLS EXHIBIT POLYSOMY)

CHROMOSOME 10 CENTROMERE - INTACT (NO LOSS)

PTEN - INTACT (NO LOSS)

9p21 - LOSS (42% OF TUMOR CELLS EXHIBIT LOSS)

CHROMOSOME 9 CENTROMERE - CENTROMERE LOSS (38% OF TUMOR CELLS EXHIBIT LOSS)

2 OF 4 ABNORMAL MARKERS AND 9P21 EXHIBITS LOSS

COMMENT: A MULTIVARIATE SURVIVAL ANALYSIS OF PATIENTS WITH ANAPLASTIC ASTROCYTOMAS REVEALS THAT THE HAZARD OF SHORT SURVIVAL AMONG PATIENTS WITH 0-2 ABNORMAL MARKERS (OUT OF 4) WAS SIGNIFICANTLY LOWER THAN THAT FOUND WITH PATIENTS WITH >2 MARKERS (P=0.037) EVEN AFTER ADJUSTMENT FOR AGE EFFECT.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

Electronically signed [REDACTED]

ADDENDUM 2:

IMMUNOHISTOCHEMICAL LABELING INDEX OF TUMOR CELLS:

TISSUE TYPE: BRAIN TISSUE CONTAINING ANAPLASTIC GEMISTOCYTIC ASTROCYTOMA (WHO GRADE III; [REDACTED] BLOCK A2).

LEUCOCYTE COMMON ANTIGEN (LCA): 30% OF POSITIVE CELLS.

MGMT - POSITIVE (25% OF TUMOR CELLS)

EGFR wt - POSITIVE (2+ IN 70% OF TUMOR CELLS)

EGFR vIII - NEGATIVE (0% OF TUMOR CELLS)

S6 - POSITIVE (2+ IN 25% OF TUMOR CELLS)

AKT - POSITIVE (2+ IN 30% OF TUMOR CELLS)

MAPK - POSITIVE (2+ IN 25% OF TUMOR CELLS)

CARBONIC ANHYDRASE IX: (0%) NEGATIVE FOR EXPRESSION OF CARBONIC ANHYDRASE IX.

VEGF IMMUNOHISTOCHEMISTRY: NEGATIVE (2 x 2% = score 4). Intensity x distribution => 20 is positive.

PDGFR-A IMMUNOHISTOCHEMISTRY: WIDESPREAD (90%) FOR CYTOPLASMIC AND/OR MEMBRANE REACTIVITY.

PDGFR-B IMMUNOHISTOCHEMISTRY: WIDESPREAD (60%) FOR CYTOPLASMIC AND/OR MEMBRANE REACTIVITY.

VEGFR2(KDR) IMMUNOHISTOCHEMISTRY: POSITIVE (2 x 15% = score 30). Intensity x distribution => 20 is positive.

Please see Image Cytometry Report [REDACTED] for results of supplementary tests.

I certify that I personally conducted the diagnostic evaluation of the above

[page 3 of 4]
specimen(s) and have rendered the above diagnosis(es).

Electronically signed: [REDACTED]

ADDENDUM 3:

MGMT PROMOTER METHYLATION REAL TIME PCR ANALYSIS

Received [REDACTED] from [REDACTED] is a copy of an MGMT Promoter Methylation Assay, obtained at the request of [REDACTED], on paraffin block [REDACTED]. The complete report from [REDACTED] is on file in the [REDACTED].

Result:

MGMT PROMOTER METHYLATION NOT DETECTED.

Methylation of the MGMT (O(6)-methylguanine-DNA methyltransferase) gene was not detected using methylation specific PCR technologies.

Background:

MGMT (O(6)-methylguanine-DNA methyltransferase) is a DNA repair enzyme that is involved in the repair of damage caused by a variety of DNA crosslinking compounds, including alkylating agents. Increased methylation of the MGMT gene promoter region causes diminished or silenced expression of the gene, making cells more sensitive to DNA damage. This relationship has been shown for glioblastomas and alkylating agents such as Temodar(R) (temozolomide). Approximately 40% to 45% of glioblastoma multiforme (GBM) tumors exhibit MGMT gene methylation. Retrospective studies have shown that detection of MGMT promoter methylation in tumor samples is associated with an increased likelihood of a favorable response to temozolomide.

Methodology:

DNA is isolated from formalin-fixed, paraffin-embedded (FFPE) specimen. Molecular analysis of the MGMT gene is performed by methylation-specific PCR and detected on [REDACTED]. Molecular-based testing is highly accurate but as in any laboratory test, rare diagnostic errors may occur.

Results of this test are for Investigational Purposes Only. The performance characteristic of this assay have been determined by [REDACTED]. The result should not be used as a diagnostic procedure without confirmation of the diagnosis by another medically established diagnostic product or procedure.

References:

1. Vlassenbroeck I. et al. Validation of Real-Time Methylation-Specific PCR to Determine O(6)-Methylguanine-DNA Methyltransferase Gene Promoter Methylation in Glioma. J. Molecular Diagnostics 10; 4:332-337. 2008.
2. Hegi M. et al. MGMT Gene Silencing and Benefit from Temozolomide in Glioblastoma. New England J Medicine 352; 10:997-1003. 2005.
3. Brandes A. et al. MGMT Promoter Methylation Status Can Predict the Incidence and Outcome of Pseudoprogression After Concomitant Radiochemotherapy in Newly Diagnosed Glioblastoma Patients. J. Clinical Oncology 26; 13:2192-2197. 2008.
4. Hau P. et al. MGMT Methylation Status: The Advent of Stratified Therapy in Glioblastoma. Disease Markers 23:97-104. 2007.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

[page 4 of 4]
Electronically signed: [REDACTED]
Performed by: SURGICAL PATHOLOGY

Ordering MD:

Criteria	lw 10/1/13	Yes	No

[REDACTED] Printed by

Source: NCI Genomic Data Commons file 87858dea-5a82-4da5-9ace-2510c561442b (TCGA-E1-A7YK.13A02681-DC77-4548-9DA0-C6224BCFE305.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).